Gene-level copy-number profile of tumor specimen ALCH-B3A4-TTP1-A from ALCHEMIST case ALCH-B3A4, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 75.4 years (27,545 days).
Specimen ALCH-B3A4-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7942adcd-48ad-4792-8cef-1f71a38fe392.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3A4-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,712 have no estimate.
https://portal.gdc.cancer.gov/files/97ecfcad-a560-4126-82fa-5c5181057242

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 43; copy number 1: 13,046; copy number 2: 43,228; copy number 3: 2,590; copy number 4: 4.

Homozygous deletions (total copy number 0; autosomes only): 35 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–71,585, 9 genes: DDX11L1, WASH7P, MIR6859-1, MIR1302-2HG, MIR1302-2, FAM138A, OR4G4P, OR4G11P, OR4F5.
- chr1:89,551–91,105, 1 gene (within-gene range 0–1): AL627309.3.
- chr1:257,864–632,616, 15 genes (within-gene range 0–2): AP006222.1, AP006222.2, RPL23AP24, AL732372.1, AL732372.2, WBP1LP7, OR4F29, CICP7, AL732372.3, U6, AC114498.1, MTND1P23, MTND2P28, MTCO1P12, AC114498.2.
- chr8:46,028,804–46,028,892, 1 gene: AC118650.1.
- chr8:144,683,169–144,683,464, 1 gene: Metazoa_SRP.
- chr10:95,141,925–95,168,425, 1 gene: AL157834.4.
- chr14:74,239,449–74,262,738, 1 gene: VSX2.
- chr14:92,936,914–93,184,923, 4 genes: ITPK1, ITPK1-AS1, CYB5AP3, MOAP1.
- chr17:2,720,801–2,749,504, 2 genes (within-gene range 0–1): AC005696.4, CCDC92B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 10,199. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
